Somatic mutation profile of tumor specimen TCGA-2G-AAGW-01A (aliquot TCGA-2G-AAGW-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAGW, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Yolk sac tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 38.9 years (14,197 days).
Specimen TCGA-2G-AAGW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 151a4206-c89f-422d-a5f2-d6b2133f53ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGW-10A (Blood Derived Normal), aliquot TCGA-2G-AAGW-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8ddcab3-1ccf-4b27-a2b7-fb603bfbb128

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, In Frame Del 2, 3'UTR 1, 5'UTR 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.3233G>C p.R1078T | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV51925462; called by muse, mutect2, varscan2
- ASXL3 | c.4205C>T p.A1402V | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs763759484; called by muse, mutect2, varscan2
- GDF2 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs782796080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMPD3 | c.1558_1560del p.D520del | In Frame Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs754343955; called by pindel, varscan2
- TAS1R3 | c.198_200del p.S67del | In Frame Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs1312261579; called by pindel, varscan2
- TRMT6 | c.820A>G p.M274V | Missense Mutation (SNP) | VAF 68/110 reads (62%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs760219917; called by muse, mutect2, varscan2
- TSHZ1 | c.2213C>T p.P738L (on ENST00000580243 / NM_001308210.2; = p.P693L on NM_005786.6) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs370322226; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BICDL1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL21A1 | c.890T>C p.L297S | Missense Mutation (SNP) | VAF 24/261 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DBNL | c.809C>A p.T270N (on ENST00000448521 / NM_001014436.3; = p.T271N on NM_014063.7) | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DDX23 | c.864C>T p.P288= | Splice Region (SNP) | VAF 40/130 reads (31%) | called by muse, mutect2, varscan2
- EPHA5 | c.2727G>T p.Q909H | Missense Mutation (SNP) | VAF 18/265 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2
- GPR52 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- KMT2C | c.8210del p.N2737Ifs*13 | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- NOTCH3 | c.1334C>G p.T445R | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PALLD | c.1012G>C p.D338H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- QPCT | c.919C>A p.H307N | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, varscan2
- SULF1 | c.1447C>T p.L483F | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- TMPRSS13 | c.1710C>A p.S570R | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBAP2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARID5A | c.1617G>T p.L539= | Silent (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- KCNH4 | c.1104C>T p.V368= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs768719248, COSV52920222; called by muse, mutect2, varscan2
- RESF1 | c.4308T>C p.S1436= | Silent (SNP) | VAF 148/359 reads (41%) | called by muse, mutect2, varscan2
- SLC25A27 | c.169C>A p.R57= | Silent (SNP) | VAF 22/105 reads (21%) | called by muse, mutect2, varscan2
- SLFN5 | c.1671A>T p.T557= | Silent (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- ARHGEF2 | c.-39G>T | 5'UTR (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- KCNC4 | c.*536C>A | 3'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as COSV63926003; called by muse, varscan2
